Gene-level copy-number profile of tumor specimen TCGA-CV-7178-01A from TCGA case TCGA-CV-7178, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.1 years (23,430 days).
Specimen TCGA-CV-7178-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4fd5c548-0e9c-4db2-81a9-4fa8c47d7d03.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7178-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8dc04653-6cfb-4522-91f7-36e120362944

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,960; copy number 2: 32,123; copy number 3: 11,313; copy number 4: 5,870; copy number 5: 4,098; copy number 6: 293; copy number 7: 1,323; copy number 8: 540; copy number 9: 54; copy number 11: 49; copy number 12: 160; copy number 20: 1; copy number 23: 17; copy number 27: 1; copy number 34: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7178-01A-21D-2010-01): tumor purity 0.45, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,553 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:170,601,662–177,223,958, 143 genes, copy number 5 (broad region; genes not listed).
- chr2:177,229,191–177,265,515, 3 genes, copy number 5: DNAJC19P5, MIR3128, AC079305.1.
- chr4:66,431,092–66,431,521, 1 gene, copy number 8: RPS23P3.
- chr5:58,198–29,600,868, 446 genes, copy number 5 (broad region; genes not listed).
- chr5:39,371,675–39,462,300, 1 gene, copy number 5 (within-gene range 2–5): DAB2.
- chr5:44,066,624–44,066,731, 1 gene, copy number 5: RNU6-381P.
- chr5:44,495,099–44,828,592, 7 genes, copy number 7: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr7:70,972–41,133,507, 729 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr7:63,011,463–88,756,725, 507 genes, copy number 8 (broad region; genes not listed).
- chr7:88,794,106–88,795,737, 1 gene, copy number 8: TEX47.
- chr8:46,028,804–46,974,617, 19 genes, copy number 20–27: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4.
- chr8:48,294,026–48,931,288, 17 genes, copy number 34: IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2.
- chr8:53,162,339–145,066,685, 1,436 genes, copy number 5–7 (broad region; genes not listed).
- chr11:65,066,300–67,723,455, 193 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:67,735,608–67,736,559, 1 gene, copy number 6: AP003385.5.
- chr11:68,460,731–80,762,826, 345 genes, copy number 5–11 (broad region; genes not listed).
- chr14:21,918,188–22,530,378, 99 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
